Somatic mutation profile of tumor specimen TARGET-30-PANBSP-01A (aliquot TARGET-30-PANBSP-01A-01W) from TARGET case TARGET-30-PANBSP, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 2.9 years (1,064 days).
Specimen TARGET-30-PANBSP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e379cc2-75cf-4cbf-9a78-1e39dcf5fd63.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PANBSP-10A (Blood Derived Normal), aliquot TARGET-30-PANBSP-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b5b9ddd-2c8e-4aed-828a-a6b7bf2e5808

The open-access MAF lists 24 somatic variants for this specimen: 22 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 18, Silent 2, Frame Shift Del 1, Frame Shift Ins 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 94/368 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CPM | c.246G>T p.M82I | Missense Mutation (SNP) | VAF 148/379 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as COSV58032096; called by muse, mutect2, varscan2
- FBXL13 | c.312G>C p.K104N | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.273); catalogued as COSV57535415, COSV57542994, COSV57543838; called by muse, mutect2
- GPRASP1 | c.745T>C p.S249P | Missense Mutation (SNP) | VAF 285/556 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64354942; called by muse, mutect2, varscan2
- GPRIN3 | c.766G>A p.G256S | Missense Mutation (SNP) | VAF 71/162 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as COSV60884271; called by muse, mutect2, varscan2
- IL7R | c.1216C>A p.L406I | Missense Mutation (SNP) | VAF 60/118 reads (51%) | SIFT tolerated (0.35); PolyPhen benign (0.328); catalogued as COSV57406426; called by muse, mutect2, varscan2
- MCM3AP | c.5647C>T p.L1883F | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52436896; called by muse, mutect2, varscan2
- PRICKLE3 | c.345C>A p.D115E | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as COSV66234088; called by muse, mutect2, varscan2
- RFPL2 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 50/334 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780514943, COSV50708892; called by muse, mutect2, varscan2
- SI | c.3182G>C p.R1061T | Missense Mutation (SNP) | VAF 144/266 reads (54%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.843); catalogued as rs1033321684, COSV52268363; called by muse, mutect2, varscan2
- SLC4A3 | c.3108dup p.L1037Afs*35 | Frame Shift Ins (INS) | VAF 24/204 reads (12%) | catalogued as rs757961785; called by mutect2, varscan2
- SP110 | c.431C>A p.P144H | Missense Mutation (SNP) | VAF 310/643 reads (48%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs151199258; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMEM19 | c.632C>A p.P211Q | Missense Mutation (SNP) | VAF 141/333 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56998900; called by muse, mutect2, varscan2
- TNS4 | c.1651A>T p.K551* | Nonsense Mutation (SNP) | VAF 625/906 reads (69%) | catalogued as COSV54183678; called by muse, mutect2, varscan2
- TOPBP1 | c.727G>A p.V243M | Missense Mutation (SNP) | VAF 56/171 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53432951; called by muse, mutect2, varscan2
- TPTE2 | c.1109C>A p.P370H (on ENST00000400230 / NM_199254.2; = p.P293H on NM_130785.3) | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55017019; called by muse, mutect2, varscan2
- UNC93B1 | c.1092C>T p.G364= | Splice Region (SNP) | VAF 8/13 reads (62%) | catalogued as rs202181767, COSV57099681; called by muse, varscan2
- VPS13C | c.11153C>A p.T3718K (on ENST00000644861 / NM_020821.3; = p.T3675K on NM_017684.5) | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.109); catalogued as COSV51126948; called by mutect2, varscan2
- COL3A1 | c.3266del p.G1089Afs*147 | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | called by mutect2, pindel, varscan2
- DCLRE1A | c.325C>G p.H109D | Missense Mutation (SNP) | VAF 12/441 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2
- PSMD3 | c.257T>G p.V86G | Missense Mutation (SNP) | VAF 42/447 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.396); called by muse, mutect2
- ZNF462 | c.6481T>A p.S2161T | Missense Mutation (SNP) | VAF 29/342 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.107); called by muse, mutect2
- ERCC6L | c.1167T>C p.H389= | Silent (SNP) | VAF 153/362 reads (42%) | catalogued as rs1470971581, COSV57819663; called by muse, mutect2, varscan2
- TLR5 | c.108C>T p.C36= | Silent (SNP) | VAF 48/106 reads (45%) | catalogued as rs918811044, COSV60558113; called by muse, mutect2, varscan2
